MMRF case MMRF_1358 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/fbb21714-2fc5-47ad-8aae-118bc54612e3

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.6 years (27,262 days); ISS stage: II; Days to last known disease status: 523 days (1.4 years); Days to last follow up: 523 days (1.4 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 194 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 121 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 194 days; Days to treatment end: 313 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 194 days; Days to treatment end: 327 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 327 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -31 (ECOG 2): M Protein 7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 229 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.584 mg/dL; Immunoglobulin G 74.4 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 4.4 µg/mL; Lactate Dehydrogenase 4.8 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.76 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.18 mmol/L; Albumin 24 g/L; Total Protein 12.2 g/dL; Glucose 5.72 mmol/L.
- Day 58 (ECOG 3): M Protein 3.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 106 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 36.9 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.08 g/L; Hemoglobin 5.64 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.15 mmol/L; Albumin 30 g/L; Total Protein 9.5 g/dL; Glucose 5.72 mmol/L.
- Day 149 (ECOG 3): M Protein 3.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 71.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 35.3 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.03 g/L; Hemoglobin 5.27 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.09 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.13 mmol/L; Albumin 31 g/L; Total Protein 8.8 g/dL; Glucose 5.28 mmol/L.
- Day 236 (ECOG 3): M Protein 2.57 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.943 mg/dL; Immunoglobulin G 29.9 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.1 g/L; Hemoglobin 5.89 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.35 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.13 mmol/L; Albumin 33 g/L; Total Protein 8.1 g/dL; Glucose 5.67 mmol/L.
- Day 338 (ECOG 3): M Protein 1.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 25.1 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.12 g/L; Hemoglobin 6.08 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.78 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 7.8 g/dL; Glucose 5.17 mmol/L.
- Day 425 (ECOG 1): M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 27.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.77 mg/dL; Immunoglobulin G 27.6 g/L; Immunoglobulin A 1.07 g/L; Immunoglobulin M 0.14 g/L; Hemoglobin 5.95 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.11 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.05 mmol/L; Albumin 33 g/L; Total Protein 7.7 g/dL; Glucose 4.9 mmol/L.
- Day 523 (ECOG 1): M Protein 2.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 22.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.03 mg/dL; Immunoglobulin G 24.9 g/L; Immunoglobulin A 1.19 g/L; Immunoglobulin M 0.17 g/L; Hemoglobin 6.01 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.01 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Albumin 34 g/L; Total Protein 8.1 g/dL; Glucose 5.72 mmol/L.

Other clinical attributes
- Day -31: Weight: 42 kg; Height: 163 cm.

Biospecimens (2 samples)
- Sample MMRF_1358_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -31 days.
- Sample MMRF_1358_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -31 days.
